Gene-level copy-number profile of tumor specimen MP2PRT-PAUSLU-TTR1-A from MP2PRT case MP2PRT-PAUSLU, project MP2PRT-WT (Molecular Profiling to Predict Response to Treatment - Wilms Tumor). Sex at birth: male; Vital status: Alive; Primary diagnosis: Nephroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 4.1 years (1,484 days).
Specimen MP2PRT-PAUSLU-TTR1-A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Biospecimen anatomic site: Abdomen; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ef56b5e4-f99f-4488-b871-f4f224fbb24e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAUSLU-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,862 have no estimate.
https://portal.gdc.cancer.gov/files/1601b10b-e170-4677-9251-0c606e37076c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 362; copy number 2: 12,122; copy number 3: 8,177; copy number 4: 29,445; copy number 5: 3,759; copy number 6: 3,465; copy number 7: 373; copy number 8: 217; copy number 9: 345; copy number 10: 333; copy number 11: 163.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 841 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–162,370,475, 840 genes, copy number 9–11 (within-gene range 6–11) (broad region; genes not listed).
- chr1:196,774,813–196,795,407, 1 gene, copy number 11: CFHR3.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
